Somatic mutation profile of tumor specimen TCGA-UY-A8OB-01A (aliquot TCGA-UY-A8OB-01A-12D-A42E-08) from TCGA case TCGA-UY-A8OB, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 64.0 years (23,360 days).
Specimen TCGA-UY-A8OB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17fcccbe-9d4f-4333-ab18-c0f74fe64250.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UY-A8OB-11A (Solid Tissue Normal), aliquot TCGA-UY-A8OB-11A-12D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/571d4646-eab6-4c79-8c63-22efbc6f2f85

The open-access MAF lists 358 somatic variants for this specimen: 286 protein-altering or splice-affecting, 66 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 248, Silent 66, Nonsense Mutation 18, Frame Shift Del 8, Splice Site 6, RNA 3, Splice Region 2, Intron 2, In Frame Ins 1, In Frame Del 1, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LYN | c.1090A>C p.I364L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV101319622; called by muse, mutect2, varscan2
- LYN | c.1091T>A p.I364N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101319623, COSV70205735; called by muse, mutect2, varscan2
- TP53 | c.626_627del p.R209Kfs*6 | Frame Shift Del (DEL) | VAF 18/38 reads (47%) | catalogued as rs1057517840; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA2 | c.5362A>G p.K1788E (on ENST00000614293; = p.K1758E on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.025); catalogued as rs1334486496, COSV99688081; called by muse, mutect2, varscan2
- ABCA2 | c.3969C>A p.F1323L (on ENST00000614293; = p.F1293L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.214); catalogued as rs1404507698, COSV99688083; called by muse, mutect2
- ABCD2 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100429668; called by muse, mutect2
- ABHD18 | c.937A>T p.N313Y (on ENST00000398965 / NM_001039717.2; = p.N220Y on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/59 reads (78%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV101180814; called by muse, mutect2, varscan2
- ACAP3 | c.1017G>A p.K339= | Splice Region (SNP) | VAF 6/33 reads (18%) | catalogued as rs750106673, COSV100686608, COSV61223268; called by muse, mutect2
- ACRBP | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.185); catalogued as COSV99976217; called by muse, mutect2, varscan2
- ACSBG1 | c.2153T>G p.F718C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV99357638; called by muse, mutect2, varscan2
- ADAMTS5 | c.2746T>C p.S916P | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV99538034; called by muse, mutect2, varscan2
- ADIPOR1 | c.547T>C p.C183R | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100579603; called by muse, mutect2, varscan2
- AHNAK2 | c.11828C>G p.A3943G | Missense Mutation (SNP) | VAF 99/271 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.155); catalogued as COSV100318319; called by muse, mutect2, varscan2
- AHR | c.1697T>C p.F566S | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV99620003; called by muse, mutect2
- AL121899.2 | c.245A>G p.Y82C | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101198579; called by muse, mutect2, varscan2
- ALDH18A1 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100973251; called by muse, mutect2, varscan2
- ALPK2 | c.2845G>C p.E949Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as COSV100864568; called by muse, mutect2, varscan2
- AMER2 | c.1544A>G p.E515G | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100766333; called by muse, mutect2
- AMOT | c.1285G>A p.A429T (on ENST00000371959 / NM_001113490.1; = p.A20T on NM_133265.3) | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV100495354; called by muse, mutect2, varscan2
- ANGPTL4 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as rs201770562, CM164625, COSV100035206; called by muse, mutect2, varscan2
- ANKRD30A | c.1186A>G p.M396V (on ENST00000611781; = p.M340V on NM_052997.2) | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV100654079; called by muse, mutect2, varscan2
- ANXA2R | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100148697; called by muse, mutect2, varscan2
- AP1B1 | c.2144C>A p.S715* | Nonsense Mutation (SNP) | VAF 52/139 reads (37%) | catalogued as COSV100434687; called by muse, mutect2, varscan2
- ARAP2 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100394986; called by muse, mutect2, varscan2
- ARHGAP18 | c.397A>C p.S133R | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as COSV100936359; called by muse, mutect2, varscan2
- ASB14 | c.1336G>C p.D446H | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); catalogued as COSV101274199; called by muse, mutect2, varscan2
- ASIC4 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs1358746352, COSV100761842, COSV100761950; called by muse, mutect2, varscan2
- ATG2A | c.502A>G p.K168E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV101034612; called by muse, varscan2
- ATL1 | c.676T>C p.S226P | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100613206; called by muse, mutect2, varscan2
- ATM | c.2530G>C p.G844R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99590725; called by muse, mutect2, varscan2
- AURKC | c.718G>C p.E240Q (on ENST00000302804 / NM_001015878.2; = p.E206Q on NM_003160.3) | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV57141596; called by muse, mutect2, varscan2
- AVL9 | c.1913A>G p.Q638R | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as rs1257137851, COSV100594718; called by muse, mutect2
- BBOF1 | c.185A>G p.K62R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs1471115525, COSV100592292; called by muse, mutect2
- BCAS2 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as COSV101058641; called by muse, mutect2, varscan2
- BDP1 | c.2574G>T p.K858N | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV100703356; called by muse, mutect2, varscan2
- BIRC6 | c.14065T>A p.L4689M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101428500; called by muse, mutect2, varscan2
- BUB1 | c.2859G>A p.M953I | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100241468; called by muse, mutect2, varscan2
- C11orf49 | c.232T>C p.F78L | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99562457; called by muse, mutect2, varscan2
- C16orf71 | c.383A>T p.E128V | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV100173047; called by muse, mutect2
- CACNA2D1 | c.2700T>G p.Y900* (on ENST00000356253 / NM_001366867.1; = p.Y888* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 29/72 reads (40%) | catalogued as COSV100666963; called by muse, mutect2, varscan2
- CC2D1B | c.1114C>G p.P372A | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99430136; called by muse, mutect2, varscan2
- CCDC97 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.212); catalogued as rs1402240509, COSV99523809; called by muse, mutect2
- CD22 | c.1763A>G p.E588G | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99323520; called by muse, mutect2, varscan2
- CDC42BPG | c.4099C>T p.L1367F | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV61349046; called by muse, mutect2, varscan2
- CDK17 | c.394A>G p.I132V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs140389429; called by muse, mutect2, varscan2
- CDKN2AIP | c.404-1G>C p.X135_splice | Splice Site (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100187678; called by muse, mutect2, varscan2
- CELSR1 | c.4013T>C p.F1338S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99419171; called by muse, mutect2, varscan2
- CENPJ | c.3886A>G p.K1296E | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99693882; called by muse, mutect2, varscan2
- CENPJ | c.3750G>C p.Q1250H | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV55047851; called by muse, mutect2, varscan2
- CENPJ | c.1684G>C p.E562Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.294); catalogued as COSV101121548; called by muse, mutect2, varscan2
- CEP350 | c.9241G>A p.E3081K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100854993; called by muse, mutect2, varscan2
- CERT1 | c.770G>A p.R257Q (on ENST00000405807 / NM_001130105.1; = p.R129Q on NM_005713.3) | Missense Mutation (SNP) | VAF 58/72 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs916090030, COSV54662280; called by muse, mutect2, varscan2
- CFAP206 | c.473-2A>C p.X158_splice | Splice Site (SNP) | VAF 31/40 reads (78%) | catalogued as COSV99739839; called by muse, mutect2, varscan2
- CFAP57 | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV100994017; called by muse, mutect2, varscan2
- CHD5 | c.3181G>C p.E1061Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV99314362; called by muse, varscan2
- CHST11 | c.566T>C p.F189S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100359714; called by muse, mutect2, varscan2
- CIAO1 | c.874T>G p.F292V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as COSV99720484; called by muse, mutect2, varscan2
- CLK1 | c.569T>G p.V190G | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100362373; called by muse, mutect2, varscan2
- CMIP | c.1427T>C p.L476S (on ENST00000537098 / NM_198390.2; = p.L382S on NM_030629.3) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101220944; called by muse, mutect2, varscan2
- CNOT1 | c.1327C>T p.R443* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100409730; called by muse, mutect2, varscan2
- COL7A1 | c.4054C>T p.P1352S | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100096974; called by muse, mutect2, varscan2
- CPN2 | c.1422A>T p.E474D | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV100103200; called by muse, mutect2, varscan2
- CRB2 | c.3260A>G p.E1087G | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs1278691730, COSV100749707; called by muse, mutect2
- CRYGS | c.128A>G p.E43G | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV100330026; called by muse, mutect2, varscan2
- CSMD3 | c.1645G>A p.G549S (on ENST00000297405 / NM_001363185.1; = p.G445S on NM_052900.3) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV99841375; called by muse, mutect2, varscan2
- CSTF3 | c.1363T>C p.S455P | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV100124237; called by muse, mutect2, varscan2
- CTR9 | c.2805G>C p.K935N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.966); catalogued as COSV100797334, COSV100797409; called by muse, mutect2, varscan2
- CUL9 | c.769T>C p.F257L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV99335732; called by muse, mutect2, varscan2
- CYP11B2 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV100011182, COSV100011244; called by muse, mutect2, varscan2
- DCP2 | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); catalogued as COSV66618111; called by muse, mutect2, varscan2
- DENND3 | c.2019C>G p.F673L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99371340; called by muse, mutect2, varscan2
- DEPTOR | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99639011; called by muse, mutect2, varscan2
- DHTKD1 | c.2477A>G p.K826R | Missense Mutation (SNP) | VAF 15/302 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs772739418, COSV99536727; called by muse, mutect2
- DIAPH2 | c.3260T>C p.L1087S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100234145; called by muse, mutect2, varscan2
- DMBX1 | c.508C>G p.L170V | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.048); catalogued as COSV100760841; called by muse, mutect2, varscan2
- DMXL2 | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1443260908, COSV99196806; called by muse, mutect2, varscan2
- DNAH10 | c.1419C>G p.F473L (on ENST00000409039; = p.F412L on NM_207437.3) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.071); catalogued as rs1227665578, COSV101292460; called by muse, mutect2, varscan2
- DNAJC16 | c.254A>C p.K85T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101012617; called by muse, mutect2, varscan2
- DOT1L | c.4435A>G p.M1479V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.019); catalogued as COSV101288743; called by muse, mutect2, varscan2
- DST | c.17990A>C p.K5997T (on ENST00000361203 / NM_001374722.1; = p.K3694T on NM_015548.5) | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV99758340; called by muse, mutect2, varscan2
- DYNC2H1 | c.8260C>G p.Q2754E | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV62105977; called by muse, mutect2, varscan2
- EDA2R | c.326A>T p.K109M | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99490833; called by muse, mutect2, varscan2
- EIF3D | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as COSV99341653; called by muse, mutect2, varscan2
- ENOX1 | c.1751G>C p.G584A | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99816602; called by muse, mutect2, varscan2
- EPHA1 | c.2275C>G p.Q759E | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99314391; called by muse, mutect2, varscan2
- ERN2 | c.2323G>C p.V775L | Missense Mutation (SNP) | VAF 75/224 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV99891951; called by muse, mutect2, varscan2
- ESF1 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.257); catalogued as rs1248252291, COSV99176448; called by muse, mutect2, varscan2
- ESPL1 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as rs1201326649, COSV99228900; called by muse, mutect2, varscan2
- FAM171B | c.1349G>C p.R450T | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.898); catalogued as COSV100488818, COSV59001776; called by muse, mutect2, varscan2
- FAM83G | c.159G>C p.E53D | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV100525345; called by muse, mutect2, varscan2
- FER1L6 | c.1619A>G p.Q540R | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV101206080; called by muse, mutect2, varscan2
- FGFR1 | c.2203G>C p.D735H (on ENST00000447712 / NM_023110.3; = p.D733H on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CD0911325, COSV100248808, COSV58346919; called by muse, mutect2, varscan2
- FMN1 | c.2299G>C p.E767Q (on ENST00000616417 / NM_001277313.2; = p.E544Q on NM_001103184.4) | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV100569118, COSV57919829; called by muse, mutect2, varscan2
- FOLH1 | c.269T>C p.F90S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.154); catalogued as COSV99923581; called by muse, mutect2, varscan2
- GDAP1 | c.656T>C p.V219A | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as CM094277, CM114981, COSV55186121; called by muse, mutect2, varscan2
- GDAP1L1 | c.600G>T p.E200D | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100697434, COSV100697628; called by muse, mutect2, varscan2
- GIMAP8 | c.889A>T p.K297* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as COSV100217609; called by muse, mutect2, varscan2
- GPATCH8 | c.2210G>A p.G737E | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); catalogued as COSV100132752; called by muse, mutect2, varscan2
- GPNMB | c.1514G>C p.G505A (on ENST00000381990 / NM_001005340.2; = p.G493A on NM_002510.3) | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.675); catalogued as COSV99326647; called by muse, mutect2
- GTF3C1 | c.1514G>C p.R505P | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100649456, COSV100649593; called by muse, mutect2, varscan2
- GUCY2F | c.2136G>T p.W712C | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99485373; called by muse, mutect2, varscan2
- GYG2 | c.1159C>G p.P387A | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV100089165; called by muse, mutect2
- H2BC1 | c.94A>G p.K32E | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as COSV99219479; called by muse, mutect2, varscan2
- H6PD | c.1894A>G p.N632D | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332742603, COSV101072508; called by muse, mutect2, varscan2
- HCN1 | c.469C>A p.L157I | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.305); catalogued as COSV100301387, COSV57543953; called by muse, mutect2, varscan2
- HIPK3 | c.74A>C p.K25T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100305916; called by muse, mutect2, varscan2
- HMGXB4 | c.409T>A p.S137T | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.315); catalogued as COSV99330193; called by muse, mutect2, varscan2
- ICE2 | c.2948G>C p.*983Sext*14 | Nonstop Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV99831684; called by muse, mutect2, varscan2
- IFRD2 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1553709552, COSV100269680; called by muse, mutect2
- IGF2BP2 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.142); catalogued as COSV100649400; called by muse, mutect2, varscan2
- IGKV1D-13 | c.140C>A p.A47E | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs529942021; called by muse, mutect2, varscan2
- IRAG1 | c.1661G>C p.R554T | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101351416; called by muse, mutect2, varscan2
- IRS1 | c.3355T>C p.F1119L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100524769; called by muse, mutect2, varscan2
- IRX1 | c.1186G>C p.A396P | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs755744445, COSV100116650, COSV57359281; called by muse, mutect2, varscan2
- ITGA11 | c.308T>C p.M103T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100241925; called by muse, mutect2, varscan2
- JMJD1C | c.3578C>T p.S1193F | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs755766861, COSV100550725; called by muse, mutect2, varscan2
- KALRN | c.4630T>C p.F1544L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99566041; called by mutect2, varscan2
- KANK3 | c.1886A>T p.Y629F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100445078; called by muse, mutect2, varscan2
- KIAA0319 | c.755A>C p.K252T | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as COSV100985704; called by muse, mutect2, varscan2
- KIAA2026 | c.4024A>G p.T1342A | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.088); catalogued as rs539282898, COSV101199128; called by muse, mutect2, varscan2
- KIF21B | c.2975T>C p.I992T | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV100144831; called by muse, mutect2
- KLHL40 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs911558073, COSV99825664; called by muse, mutect2, varscan2
- KRT40 | c.713T>G p.L238R | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100898870; called by muse, mutect2, varscan2
- LILRA1 | c.914C>G p.S305C | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV99252026; called by muse, mutect2, varscan2
- LLGL1 | c.1931T>A p.L644Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100375544; called by muse, mutect2, varscan2
- LRAT | c.545G>C p.C182S | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV100312141; called by muse, mutect2, varscan2
- LRRCC1 | c.773T>C p.L258S | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.4); catalogued as rs1413963324, COSV100835523; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV101012215; called by muse, mutect2, varscan2
- MAN1A2 | c.349A>T p.K117* | Nonsense Mutation (SNP) | VAF 24/89 reads (27%) | catalogued as COSV100741015; called by muse, mutect2, varscan2
- MAN2B2 | c.211C>G p.R71G | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99577776; called by muse, mutect2, varscan2
- MAP1B | c.3416C>G p.P1139R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV99702719; called by muse, mutect2, varscan2
- MAP4K1 | c.1049G>C p.R350T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.096); catalogued as rs1416113409, COSV101204317; called by muse, mutect2, varscan2
- MAP4K5 | c.1585A>C p.T529P | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99184779; called by muse, mutect2, varscan2
- MARK1 | c.470A>T p.K157I | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV100857399; called by muse, mutect2, varscan2
- MCM10 | c.1112C>G p.S371C (on ENST00000484800 / NM_182751.3; = p.S370C on NM_018518.5) | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs765572804, COSV101098311; called by muse, mutect2, varscan2
- MDM1 | c.1526A>G p.K509R | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.508); catalogued as COSV100291986; called by muse, mutect2, varscan2
- MED12L | c.818T>C p.L273S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV99853990; called by muse, mutect2
- MED13L | c.1271C>G p.S424C | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); catalogued as COSV99929557; called by muse, mutect2, varscan2
- MGA | c.3743A>C p.K1248T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV99580758; called by muse, mutect2, varscan2
- MON2 | c.4105G>C p.E1369Q | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV99743090; called by muse, mutect2, varscan2
- MRPL32 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT tolerated (0.9); PolyPhen benign (0.011); catalogued as rs775745596, COSV99786287; called by muse, mutect2, varscan2
- MTA2 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.885); catalogued as rs768452845, COSV99545480; called by muse, mutect2, varscan2
- MUC16 | c.38132A>G p.K12711R | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.005); catalogued as COSV101200549, COSV67468280; called by muse, mutect2, varscan2
- MUC16 | c.38131A>T p.K12711* | Nonsense Mutation (SNP) | VAF 28/102 reads (27%) | catalogued as COSV101200550, COSV67476512; called by muse, mutect2, varscan2
- MUC5B | c.14633A>C p.K4878T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101500574; called by muse, mutect2, varscan2
- MYO1A | c.2570A>G p.K857R | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.093); catalogued as COSV55653103; called by muse, mutect2, varscan2
- MYOF | c.1199A>G p.E400G | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100825988; called by muse, mutect2, varscan2
- NCK2 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.255); catalogued as rs754330998, COSV51893725; called by muse, mutect2, varscan2
- NCKAP5L | c.1604T>C p.L535P | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV100259008; called by muse, mutect2
- NCOA5 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.039); catalogued as COSV99275812; called by muse, mutect2, varscan2
- NCOR2 | c.4784C>T p.S1595F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100657678; called by muse, mutect2, varscan2
- NDC1 | c.1505C>G p.S502C | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1390346580, COSV99323805; called by muse, mutect2, varscan2
- NEDD8 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV99164649; called by mutect2, varscan2
- NISCH | c.2329G>C p.E777Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100617511; called by muse, mutect2, varscan2
- NKX2-2 | c.741C>A p.Y247* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as rs1221836916, COSV101010604; called by muse, mutect2, varscan2
- NLK | c.595T>C p.S199P | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs1264282347, COSV101311263; called by muse, mutect2, varscan2
- NLRC5 | c.5265G>T p.Q1755H | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV99347813; called by muse, mutect2, varscan2
- NLRP11 | c.664A>G p.K222E | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as COSV100789783; called by muse, mutect2, varscan2
- NOL6 | c.1193C>G p.S398* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as COSV99954958; called by muse, mutect2, varscan2
- ONECUT2 | c.1105T>A p.S369T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101529803; called by muse, mutect2, varscan2
- OPN1LW | c.734C>G p.A245G | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs1557157843, COSV100885057; called by muse, mutect2, varscan2
- OR52H1 | c.875T>A p.M292K (on ENST00000322653; = p.M298K on NM_001005289.1) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV100497348; called by muse, mutect2, varscan2
- OR5B17 | c.638T>C p.L213S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.168); catalogued as COSV100641940; called by muse, mutect2, varscan2
- PARD3 | c.1298C>A p.S433Y | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV100401551; called by muse, mutect2, varscan2
- PCDHB7 | c.1997T>C p.F666S | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs782635712, COSV99177182; called by muse, mutect2, varscan2
- PDE11A | c.912G>A p.Q304= | Splice Region (SNP) | VAF 22/70 reads (31%) | catalogued as rs949723171, COSV53691052, COSV99613797; called by muse, mutect2, varscan2
- PDIA4 | c.1787A>G p.Y596C (on ENST00000286091 / NM_001371244.1; = p.Y595C on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs376262990; called by muse, mutect2, varscan2
- PIGR | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.738); catalogued as rs1349069697, COSV100732562, COSV100732703; called by muse, mutect2, varscan2
- PLAAT5 | c.689A>T p.E230V | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV100080558; called by muse, mutect2, varscan2
- PLK3 | c.1306T>A p.C436S | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100221228; called by muse, mutect2, varscan2
- PLPP7 | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs1263943483, COSV100952591; called by muse, mutect2, varscan2
- PMEPA1 | c.603G>T p.R201S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as rs1419929922, COSV55693721, COSV99671941; called by muse, mutect2, varscan2
- PNMA8A | c.238A>T p.S80C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100562387; called by muse, mutect2, varscan2
- PNPLA1 | c.1288T>C p.S430P (on ENST00000394571 / NM_001374623.1; = p.S335P on NM_173676.2) | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs1241082483, COSV100463416; called by muse, mutect2
- POGLUT2 | c.658T>C p.S220P | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1403602233, COSV101050811; called by muse, mutect2, varscan2
- PPIF | c.568A>G p.K190E | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.124); catalogued as rs1226384160, COSV99830955; called by muse, mutect2, varscan2
- PROCA1 | c.472G>T p.V158L (on ENST00000439862 / NM_001366301.1; = p.V130L on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as rs1355042976, COSV99972876; called by muse, mutect2, varscan2
- PSG2 | c.149A>C p.D50A | Missense Mutation (SNP) | VAF 90/448 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101290495, COSV68884183; called by muse, varscan2
- PSME4 | c.512A>G p.N171S | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1415940050, COSV101122580; called by muse, mutect2, varscan2
- PTGS1 | c.826C>G p.R276G | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV99793370, COSV99793512; called by muse, mutect2, varscan2
- PTPRU | c.3197T>A p.F1066Y | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100113312; called by muse, mutect2, varscan2
- PUM2 | c.1163C>A p.A388D | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.224); catalogued as COSV100163850; called by muse, mutect2, varscan2
- QPCTL | c.889A>G p.K297E | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.736); catalogued as COSV99171302; called by muse, mutect2
- RAD54B | c.2162A>T p.K721I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100280011; called by muse, mutect2, varscan2
- RFC2 | c.1039A>T p.K347* (on ENST00000055077 / NM_181471.3; = p.K313* on NM_002914.4) | Nonsense Mutation (SNP) | VAF 44/118 reads (37%) | catalogued as COSV99278036; called by muse, mutect2, varscan2
- RHOA | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as COSV101371152, COSV69043583, COSV99069255; called by muse, mutect2, varscan2
- RIMBP2 | c.2537A>G p.E846G | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99900019; called by muse, mutect2, varscan2
- RPL26L1 | c.206A>T p.K69M | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99442573; called by muse, mutect2, varscan2
- SCAF11 | c.4145A>G p.K1382R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV101014521; called by muse, mutect2, varscan2
- SCG2 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.014); catalogued as COSV100544825, COSV59539335; called by muse, mutect2, varscan2
- SH3GLB1 | c.713A>G p.Y238C | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs755193646, COSV100990797; called by muse, mutect2, varscan2
- SHH | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.278); catalogued as rs1473100698, COSV99793477; called by muse, mutect2, varscan2
- SLC13A4 | c.1211T>C p.F404S | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100818914; called by muse, mutect2, varscan2
- SLC15A2 | c.1703T>A p.F568Y | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99815682; called by muse, mutect2, varscan2
- SLC16A1 | c.1393G>T p.E465* | Nonsense Mutation (SNP) | VAF 32/163 reads (20%) | catalogued as COSV100856027; called by muse, mutect2, varscan2
- SLC1A5 | c.794C>G p.A265G | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV101314805; called by muse, mutect2, varscan2
- SLC43A2 | c.880C>G p.L294V | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.085); catalogued as COSV100025132; called by muse, mutect2, varscan2
- SLCO4A1 | c.1328T>C p.F443S | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs1260627160, COSV99414921; called by muse, mutect2, varscan2
- SLFN11 | c.2054A>G p.K685R | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV100390828; called by muse, mutect2, varscan2
- SMARCA4 | c.4224A>T p.K1408N | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV100758888; called by muse, mutect2
- SMO | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs202241524, COSV50826585; called by muse, mutect2
- SNRPB | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.885); catalogued as rs767441589, COSV100293431; called by muse, mutect2, varscan2
- SNTG1 | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV99384966; called by muse, mutect2, varscan2
- SORL1 | c.446C>G p.S149* | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | catalogued as COSV52755640, COSV99494747; called by muse, mutect2, varscan2
- SOX14 | c.632C>A p.T211N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100048139; called by muse, mutect2, varscan2
- SPAG17 | c.6364A>G p.K2122E | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1254964076, COSV100309842; called by muse, mutect2
- SPHKAP | c.2882C>A p.A961E | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100764288; called by muse, mutect2, varscan2
- SPTLC3 | c.412T>C p.F138L | Missense Mutation (SNP) | VAF 80/274 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV100983234; called by muse, mutect2, varscan2
- SSU72 | c.164A>C p.Y55S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99357444; called by muse, mutect2, varscan2
- ST3GAL5 | c.749T>A p.F250Y (on ENST00000377332; = p.F290Y on NM_003896.4) | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.998); catalogued as COSV100088573; called by muse, mutect2, varscan2
- STAG1 | c.2077T>C p.S693P | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs1296664528, COSV99366338; called by muse, mutect2
- STAG1 | c.2075T>C p.L692P | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.392); catalogued as COSV99366339; called by muse, mutect2
- STAT4 | c.510A>C p.E170D | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100636119; called by muse, mutect2, varscan2
- STRIP2 | c.1477G>A p.G493R | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs1279476324, COSV99973979; called by muse, mutect2, varscan2
- STRN3 | c.2225-1G>T p.X742_splice (on ENST00000357479 / NM_001083893.2; = p.X658_splice on NM_014574.4) | Splice Site (SNP) | VAF 19/49 reads (39%) | catalogued as COSV100670811; called by muse, mutect2, varscan2
- SUZ12 | c.1561A>G p.K521E | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100496983; called by muse, mutect2, varscan2
- SYK | c.115T>C p.Y39H | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434639334, COSV101002564; called by muse, mutect2, varscan2
- SYNE2 | c.3398A>G p.N1133S | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100648164; called by muse, mutect2, varscan2
- TAC3 | c.315A>C p.Q105H | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV100269900; called by muse, mutect2
- TAF1B | c.1606_1607insATA p.S536delinsYT | In Frame Ins (INS) | VAF 13/58 reads (22%) | catalogued as COSV99722357; called by mutect2, pindel, varscan2
- TANC1 | c.107A>G p.H36R | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.137); catalogued as COSV99714637; called by muse, mutect2, varscan2
- TAOK2 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs141012429; called by muse, mutect2, varscan2
- TBCC | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99773997; called by muse, mutect2, varscan2
- TCERG1 | c.268G>C p.G90R | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.421); catalogued as COSV99695086; called by muse, mutect2, varscan2
- TDRD7 | c.1316A>C p.E439A | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV100795743; called by muse, mutect2
- TDRD7 | c.1318A>G p.S440G | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs748981064, COSV100795744; called by muse, mutect2
- TEX10 | c.1756A>G p.K586E | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.165); catalogued as rs1296482632, COSV100887901; called by muse, mutect2, varscan2
- TEX55 | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.042); catalogued as rs1245806555, COSV99817662; called by muse, mutect2, varscan2
- TFDP1 | c.437T>G p.F146C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100945967; called by muse, mutect2, varscan2
- TFDP2 | c.374G>T p.G125V (on ENST00000489671 / NM_001178139.2; = p.G64V on NM_006286.5) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100051101; called by muse, mutect2, varscan2
- TMC4 | c.331G>A p.D111N (on ENST00000617472 / NM_001145303.3; = p.D105N on NM_144686.4) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as COSV99824930; called by muse, mutect2, varscan2
- TMEM190 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); catalogued as COSV99404246; called by muse, mutect2
- TP63 | c.1660G>T p.A554S | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.145); catalogued as COSV99287893; called by muse, mutect2, varscan2
- TPRN | c.1739T>C p.F580S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100119182; called by muse, mutect2, varscan2
- TPST1 | c.880G>C p.V294L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as COSV100507240; called by muse, mutect2, varscan2
- TRIM39 | c.1089G>C p.E363D | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.09); catalogued as COSV100935866; called by muse, mutect2, varscan2
- TRPC5 | c.1647G>T p.E549D | Missense Mutation (SNP) | VAF 69/77 reads (90%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as COSV99462003; called by muse, mutect2, varscan2
- TRPM1 | c.3227+1G>C p.X1076_splice | Splice Site (SNP) | VAF 16/56 reads (29%) | catalogued as COSV99856313; called by muse, mutect2, varscan2
- TSLP | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 116/144 reads (81%) | SIFT tolerated (0.18); PolyPhen benign (0.169); catalogued as COSV100789199; called by muse, mutect2, varscan2
- TTLL5 | c.2518C>T p.H840Y | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.722); catalogued as rs371166683; called by muse, mutect2, varscan2
- TTN | c.59191A>T p.K19731* (on ENST00000591111; = p.K12307* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as COSV100621766; called by muse, mutect2, varscan2
- TTN | c.59190G>T p.R19730S (on ENST00000591111; = p.R12306S on NM_003319.4) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | PolyPhen benign (0.178); catalogued as COSV100621769, COSV60005556; called by muse, mutect2, varscan2
- TUBA1A | c.290A>G p.E97G | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.228); catalogued as COSV99853778; called by muse, mutect2
- TUT4 | c.3418A>G p.I1140V | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as COSV99932597; called by muse, mutect2, varscan2
- TXNDC16 | c.362A>C p.D121A | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99909446; called by muse, mutect2, varscan2
- UBA7 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100339812; called by muse, mutect2, varscan2
- UBE2E3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV101150519; called by muse, mutect2, varscan2
- UBE4B | c.1409T>C p.L470S (on ENST00000343090 / NM_001105562.3; = p.L341S on NM_006048.5) | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99477286; called by muse, mutect2, varscan2
- UBR4 | c.8143A>C p.T2715P | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); catalogued as COSV100921362; called by muse, mutect2, varscan2
- ULK4 | c.284A>G p.E95G | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100094077; called by muse, mutect2, varscan2
- UMOD | c.1528C>A p.P510T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100208538; called by muse, mutect2, varscan2
- UROD | c.139A>G p.R47G | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV99870337; called by muse, mutect2, varscan2
- VCAN | c.1539C>A p.F513L | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54098231, COSV99424253, COSV99426657; called by muse, mutect2, varscan2
- VEGFC | c.864A>C p.E288D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as COSV99710077; called by muse, mutect2
- WDR11 | c.121T>C p.S41P | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV99676807; called by muse, mutect2, varscan2
- WDR38 | c.427T>A p.L143I | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV100793848; called by muse, mutect2, varscan2
- WIPI2 | c.569T>G p.I190S | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99993500; called by muse, mutect2, varscan2
- WNT2 | c.697T>C p.Y233H | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs1449199103, COSV99626262; called by muse, mutect2, varscan2
- XIRP2 | c.6469G>C p.E2157Q (on ENST00000628543; = p.E2332Q on NM_152381.6) | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.294); catalogued as COSV54718438, COSV99745445; called by muse, mutect2, varscan2
- ZAN | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV100769974; called by muse, mutect2, varscan2
- ZBED4 | c.817A>G p.K273E | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as COSV99351452; called by muse, mutect2, varscan2
- ZBTB22 | c.766A>G p.K256E | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.078); catalogued as COSV99802426; called by muse, mutect2, varscan2
- ZFHX3 | c.1797T>A p.N599K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV99213817; called by muse, mutect2, varscan2
- ZNF154 | c.1129A>T p.R377* | Nonsense Mutation (SNP) | VAF 24/177 reads (14%) | catalogued as COSV101377528; called by muse, mutect2, varscan2
- ZNF181 | c.1356G>C p.L452F | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV67627064; called by muse, mutect2, varscan2
- ZNF324 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs770914514, COSV99543386; called by muse, mutect2
- ZNF337 | c.1113_1114del p.K374Afs*8 | Frame Shift Del (DEL) | VAF 13/103 reads (13%) | catalogued as rs761462493; called by mutect2, pindel, varscan2
- ZNF462 | c.1333C>G p.P445A | Missense Mutation (SNP) | VAF 67/122 reads (55%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.062); catalogued as COSV99472702; called by muse, mutect2, varscan2
- ZNF492 | c.581A>G p.K194R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV101514029; called by muse, mutect2
- ZNF699 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 40/87 reads (46%) | catalogued as rs774512739, COSV100427023; called by muse, mutect2, varscan2
- ZNF709 | c.368C>G p.S123C | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV101172242; called by muse, mutect2, varscan2
- ZNF711 | c.778G>C p.G260R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99341389; called by muse, mutect2, varscan2
- ZNRF4 | c.183C>A p.S61R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs745563478, COSV99706635; called by muse, mutect2, varscan2
- ZSCAN29 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53019639; called by muse, mutect2, varscan2
- DDB2 | c.591dup p.D198Rfs*9 | Frame Shift Ins (INS) | VAF 31/104 reads (30%) | called by mutect2, pindel, varscan2
- IL7R | c.82+2_82+34del p.X28_splice | Splice Site (DEL) | VAF 24/192 reads (13%) | called by mutect2, pindel
- IPO5 | c.2112del p.K705Nfs*2 | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | called by mutect2, pindel, varscan2
- KNSTRN | c.322_334del p.T108Sfs*30 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | called by mutect2, pindel, varscan2
- NOCT | c.896_901del p.A299_Q300del | In Frame Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- RBP3 | c.1425C>G p.I475M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- SLC15A1 | c.482_483del p.R161Ifs*10 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- SLC26A4 | c.1837A>T p.N613Y | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.516); called by muse, mutect2
- SLC9C1 | c.2013_2014del p.S672Tfs*22 | Frame Shift Del (DEL) | VAF 65/239 reads (27%) | called by mutect2, pindel, varscan2
- SLITRK6 | c.1995_1999del p.T666Sfs*4 | Frame Shift Del (DEL) | VAF 43/116 reads (37%) | called by mutect2, pindel, varscan2
- SSH1 | c.471-2_471-1del p.X157_splice | Splice Site (DEL) | VAF 27/100 reads (27%) | called by mutect2, pindel, varscan2
- ZNF600 | c.566_567del p.Q189Lfs*2 | Frame Shift Del (DEL) | VAF 42/220 reads (19%) | called by mutect2, pindel, varscan2
- ACP2 | c.1271G>A p.*424= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV99921754; called by muse, mutect2, varscan2
- AGAP2 | c.2328A>G p.P776= (on ENST00000547588 / NM_001122772.2; = p.P440= on NM_014770.4) | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV99223778; called by muse, mutect2, varscan2
- AGGF1 | c.822G>A p.L274= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs771687235, COSV100462097; called by muse, mutect2, varscan2
- ANKRD17 | c.5796G>A p.L1932= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV100429659; called by muse, mutect2, varscan2
- ANO4 | c.903T>C p.S301= (on ENST00000392977 / NM_001286615.2; = p.S266= on NM_178826.4) | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV100153360, COSV104407384; called by muse, mutect2, varscan2
- ATP4A | c.1131A>C p.T377= | Silent (SNP) | VAF 74/345 reads (21%) | catalogued as COSV99382865; called by muse, mutect2, varscan2
- BCL2L13 | c.1071A>G p.T357= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV100456343; called by muse, mutect2, varscan2
- CAPN15 | c.2127G>A p.E709= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs761362963, COSV54840494, COSV99562672; called by muse, mutect2, varscan2
- CDH17 | c.2079T>C p.D693= | Silent (SNP) | VAF 50/77 reads (65%) | catalogued as COSV99217743; called by muse, mutect2, varscan2
- CENPL | c.696T>C p.H232= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV100616411; called by muse, mutect2, varscan2
- CENPS-CORT | c.327C>G p.L109= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100259240; called by muse, mutect2, varscan2
- CFAP70 | c.2298G>A p.Q766= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV60285590; called by muse, mutect2, varscan2
- COL11A2 | c.367C>T p.L123= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as COSV100554315; called by muse, mutect2, varscan2
- DENND3 | c.1368C>T p.S456= | Silent (SNP) | VAF 58/252 reads (23%) | catalogued as COSV99371339; called by muse, mutect2, varscan2
- DGKA | c.1047A>G p.K349= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV100093255; called by muse, mutect2, varscan2
- DHX38 | c.288C>T p.G96= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs370725231; called by muse, mutect2
- DIP2A | c.2556C>T p.D852= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as rs376729838; called by muse, mutect2, varscan2
- ERAP1 | c.408C>T p.P136= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs113481697; called by muse, mutect2, varscan2
- ETV1 | c.1020T>C p.F340= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as COSV99624076; called by muse, mutect2, varscan2
- FBXO34 | c.873G>A p.L291= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV100572079; called by muse, mutect2, varscan2
- FKBP9 | c.969T>A p.L323= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV99640148; called by muse, mutect2, varscan2
- GLI3 | c.3324C>T p.Y1108= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as rs116840766, CM050639, COSV67889831; called by muse, mutect2, varscan2
- GPR12 | c.204C>T p.I68= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV67344507; called by muse, mutect2, varscan2
- IFRD2 | c.507C>T p.S169= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1553709551, COSV100269677; called by muse, mutect2
- IL1RAPL1 | c.1404T>C p.D468= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV100148795; called by muse, mutect2, varscan2
- KCNV1 | c.483G>C p.L161= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV99819266; called by muse, mutect2, varscan2
- KIAA1109 | c.2769T>G p.L923= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99167885; called by muse, mutect2, varscan2
- KIRREL1 | c.1464A>G p.E488= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as rs1174032344, COSV100780025; called by muse, mutect2
- LAMP3 | c.954T>C p.I318= | Silent (SNP) | VAF 60/269 reads (22%) | catalogued as COSV99660669; called by muse, mutect2, varscan2
- LEPROT | c.225T>A p.T75= | Silent (SNP) | VAF 66/279 reads (24%) | catalogued as COSV100756691; called by muse, mutect2, varscan2
- MAGI1 | c.675C>T p.Y225= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs761198936, COSV100442167; called by muse, mutect2, varscan2
- MED12L | c.240A>G p.K80= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99853987; called by muse, mutect2, varscan2
- NEFH | c.1503A>T p.T501= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV100151699; called by muse, mutect2, varscan2
- NPHS1 | c.2514C>G p.P838= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100800112; called by muse, mutect2, varscan2
- NRAP | c.2817C>G p.V939= (on ENST00000359988 / NM_001322945.2; = p.V904= on NM_006175.4) | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV100748525; called by muse, mutect2, varscan2
- NRF1 | c.675G>C p.G225= | Silent (SNP) | VAF 79/236 reads (33%) | catalogued as rs1289689846, COSV99781988; called by muse, mutect2, varscan2
- OPN1MW | c.879C>A p.A293= | Silent (SNP) | VAF 45/122 reads (37%) | called by muse, mutect2, varscan2
- OR10P1 | c.96T>C p.L32= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as COSV100548197; called by muse, mutect2, varscan2
- OR8J3 | c.90C>T p.V30= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV100040945, COSV56880264; called by muse, mutect2, varscan2
- PIP4K2C | c.72C>T p.F24= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV61605594, COSV61606167; called by muse, mutect2, varscan2
- PLA2G6 | c.2175G>A p.K725= | Silent (SNP) | VAF 42/56 reads (75%) | catalogued as COSV100140604; called by muse, mutect2, varscan2
- PRAMEF15 | c.819A>G p.Q273= | Silent (SNP) | VAF 96/342 reads (28%) | called by muse, mutect2, varscan2
- RBPJL | c.1341C>G p.R447= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100643523; called by muse, mutect2, varscan2
- RRAGB | c.1083G>C p.L361= (on ENST00000262850 / NM_016656.4; = p.L333= on NM_006064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV53328785; called by muse, mutect2, varscan2
- SCAF11 | c.3276G>A p.Q1092= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as rs935013488, COSV65479617; called by muse, mutect2, varscan2
- SLC17A8 | c.201C>T p.C67= | Silent (SNP) | VAF 26/113 reads (23%) | catalogued as COSV100035702; called by muse, mutect2, varscan2
- SLC22A12 | c.1053T>C p.C351= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100327756; called by muse, mutect2
- SLC22A14 | c.1398C>G p.L466= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV99828061; called by muse, mutect2, varscan2
- SLC27A5 | c.1578G>C p.S526= | Silent (SNP) | VAF 22/203 reads (11%) | catalogued as COSV99564503; called by muse, mutect2, varscan2
- SLCO1C1 | c.721C>T p.L241= | Silent (SNP) | VAF 45/83 reads (54%) | catalogued as rs1190186775, COSV56871512; called by muse, mutect2, varscan2
- SSNA1 | c.201T>C p.S67= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV100119180; called by muse, mutect2, varscan2
- STEAP4 | c.1342A>C p.R448= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100112652; called by muse, mutect2, varscan2
- STKLD1 | c.528G>C p.L176= | Silent (SNP) | VAF 94/347 reads (27%) | catalogued as rs781855875, COSV100912134; called by muse, mutect2, varscan2
- TANC1 | c.4746A>G p.L1582= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV99714639; called by muse, mutect2, varscan2
- TASOR2 | c.2526T>C p.L842= | Silent (SNP) | VAF 27/165 reads (16%) | catalogued as COSV100050732; called by muse, mutect2, varscan2
- TBC1D1 | c.2619T>C p.L873= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as COSV99791743; called by muse, mutect2, varscan2
- TFG | c.885A>T p.P295= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV99427850; called by muse, mutect2, varscan2
- TMEM236 | c.867C>G p.L289= | Silent (SNP) | VAF 93/421 reads (22%) | called by muse, mutect2, varscan2
- TPD52L2 | c.231C>G p.L77= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99410810; called by muse, mutect2, varscan2
- TPH2 | c.129A>G p.K43= | Silent (SNP) | VAF 36/44 reads (82%) | catalogued as COSV100422192; called by muse, mutect2, varscan2
- TRERF1 | c.2538A>G p.E846= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as COSV100551210; called by muse, mutect2, varscan2
- TRIM14 | c.360A>G p.L120= | Silent (SNP) | VAF 90/168 reads (54%) | catalogued as rs1378083689, COSV100419655; called by muse, mutect2, varscan2
- UAP1L1 | c.1350C>G p.L450= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV100814509; called by muse, mutect2, varscan2
- ZNF442 | c.531A>T p.G177= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as COSV99664451; called by muse, mutect2, varscan2
- ZNF492 | c.579A>G p.G193= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV101514028; called by muse, mutect2
- ZZZ3 | c.933A>G p.L311= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV100890393; called by muse, mutect2, varscan2
- DNM1P46 | n.654A>G | RNA (SNP) | VAF 8/24 reads (33%) | catalogued as rs1275121987; called by mutect2, varscan2
- LINC01600 | n.761A>G | RNA (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1515G>C | RNA (SNP) | VAF 44/71 reads (62%) | called by muse, mutect2, varscan2
- POLR2F | c.453-15093A>G | Intron (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- ZNF135 | c.-60G>A | 5'UTR (SNP) | VAF 5/50 reads (10%) | catalogued as COSV99991862; called by muse, mutect2
- ZNF665 | c.-53-9176T>A | Intron (SNP) | VAF 38/208 reads (18%) | catalogued as COSV101128675; called by muse, mutect2, varscan2
